Somatic mutation profile of tumor specimen TCGA-44-2668-01B (aliquot TCGA-44-2668-01B-02D-A271-08) from TCGA case TCGA-44-2668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.6 years (18,856 days).
Specimen TCGA-44-2668-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 768c63df-d28b-457a-a07e-4c1e80e118a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2668-10A (Blood Derived Normal), aliquot TCGA-44-2668-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3fe6c68-415b-4e08-9981-e05d05bf8e49

The open-access MAF lists 237 somatic variants for this specimen: 179 protein-altering or splice-affecting, 56 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 56, Nonsense Mutation 16, Splice Site 7, Splice Region 2, 3'Flank 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2
- ACER2 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820950; called by muse, mutect2
- ADAMTS19 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50757482; called by muse, mutect2, varscan2
- ADAMTS20 | c.4640G>A p.C1547Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67133587; called by muse, mutect2, varscan2
- ADAMTS4 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 13/182 reads (7%) | catalogued as COSV63488058; called by muse, mutect2
- ADCY2 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 14/127 reads (11%) | catalogued as COSV57879098; called by muse, mutect2, varscan2
- ADGRB3 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65401825; called by muse, mutect2, varscan2
- AFF2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60669144; called by mutect2, varscan2
- AHI1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV55629204; called by muse, mutect2
- AMOT | c.2416A>T p.T806S (on ENST00000371959 / NM_001113490.1; = p.T397S on NM_133265.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV59064774; called by muse, mutect2, varscan2
- ANKFN1 | c.1624C>G p.H542D | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV59450694; called by muse, mutect2
- AQP10 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59246622; called by muse, mutect2, varscan2
- ARHGEF7 | c.988G>T p.V330L (on ENST00000375741 / NM_001113511.2; = p.V152L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs752939884, COSV54545313, COSV54549428; called by muse, mutect2, varscan2
- ARHGEF7 | c.1533G>C p.L511F (on ENST00000375741 / NM_001113511.2; = p.L333F on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54545336; called by muse, mutect2
- ASXL3 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV52469738; called by muse, mutect2, varscan2
- BCHE | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV52258139; called by muse, mutect2
- C10orf90 | c.1908C>G p.F636L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52956156, COSV52957468; called by muse, mutect2, varscan2
- C4orf17 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV58512810; called by muse, mutect2, varscan2
- C9orf64 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV59032715; called by muse, mutect2
- CASP4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67744530; called by muse, mutect2
- CCDC28A | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs143442772; called by muse, mutect2, varscan2
- CD200R1 | c.307G>T p.E103* (on ENST00000471858 / NM_170780.3; = p.E126* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as COSV55601504; called by muse, mutect2, varscan2
- CDH10 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52584948; called by muse, mutect2, varscan2
- CDH6 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54071180, COSV54072095; called by muse, mutect2
- CDH6 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54072103; called by muse, mutect2, varscan2
- CEP20 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as COSV55384481; called by muse, mutect2
- CFI | c.1045-2A>T p.X349_splice | Splice Site (SNP) | VAF 16/207 reads (8%) | catalogued as COSV67098982; called by muse, mutect2
- CHD9 | c.5581A>T p.R1861* | Nonsense Mutation (SNP) | VAF 19/153 reads (12%) | catalogued as COSV54611874; called by muse, mutect2, varscan2
- CHRM3 | c.1592G>C p.W531S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2, varscan2
- CHRM3 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108107, COSV99697992; called by muse, mutect2, varscan2
- CNTN3 | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV55175046; called by muse, mutect2
- CNTNAP2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.184); catalogued as COSV62201650; called by muse, mutect2
- COBL | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.386); catalogued as COSV54348893; called by muse, mutect2
- COG5 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51754667; called by muse, mutect2, varscan2
- COL22A1 | c.3914C>G p.P1305R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100279666, COSV57342867; called by muse, mutect2
- COL4A6 | c.2780G>T p.G927V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859421, COSV57869363; called by muse, mutect2, varscan2
- COL6A3 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780201464, COSV55094333; called by muse, mutect2
- CSDE1 | c.1717A>G p.K573E (on ENST00000358528 / NM_001007553.3; = p.K542E on NM_007158.6) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54750316; called by muse, mutect2
- CSMD3 | c.8710G>C p.G2904R (on ENST00000297405 / NM_001363185.1; = p.G2735R on NM_052900.3) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213938; called by muse, mutect2
- CSMD3 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.761); catalogued as COSV52213955; called by muse, mutect2
- CSMD3 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52213979; called by muse, mutect2
- CYP4F2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV50001627; called by muse, mutect2, varscan2
- DCT | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV65469687; called by muse, mutect2
- DDX11 | c.1955T>G p.V652G | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506006, COSV52507585; called by muse, varscan2
- DERL1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52365157; called by muse, mutect2
- DHRSX | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 26/151 reads (17%) | catalogued as COSV58135095; called by muse, mutect2, varscan2
- DLGAP2 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.147); catalogued as COSV70099886; called by muse, mutect2
- DNAH1 | c.11593G>A p.D3865N | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56235798; called by muse, mutect2
- DNAH9 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201122944, COSV52356066; called by mutect2, varscan2
- DOCK2 | c.5153C>A p.S1718* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56945133, COSV56965266; called by muse, mutect2, varscan2
- DPP6 | c.2512T>A p.S838T (on ENST00000377770 / NM_001364500.2; = p.S776T on NM_001936.5) | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV59622580; called by muse, mutect2
- DSC3 | c.631T>C p.L211= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV64573557; called by mutect2, varscan2
- DUSP6 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54378990; called by muse, mutect2, varscan2
- DYDC2 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV55472654; called by muse, mutect2
- EIF2D | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55114118; called by muse, mutect2, varscan2
- EPHA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56036407; called by muse, mutect2
- ERICH3 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58603768; called by muse, mutect2
- ERICH6 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55799476, COSV55801319; called by muse, mutect2, varscan2
- F13A1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161514, COSV53560791; called by muse, mutect2
- FAAP24 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54280597; called by muse, mutect2
- FAM171A1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65317027; called by muse, mutect2, varscan2
- FAT4 | c.5533G>T p.V1845L | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV58691310, COSV58700791; called by muse, mutect2
- FATE1 | c.265A>T p.R89* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV64849047; called by muse, mutect2, varscan2
- FBN2 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV52496714; called by muse, mutect2, varscan2
- FBXO40 | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57524928; called by muse, mutect2, varscan2
- FGF5 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV56890586; called by muse, mutect2, varscan2
- FHOD3 | c.3458C>A p.S1153* (on ENST00000359247 / NM_001281739.3; = p.S1170* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV57176969; called by muse, mutect2, varscan2
- FLVCR2 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53162934; called by muse, mutect2
- FNDC1 | c.2791T>A p.S931T | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV51940473; called by muse, mutect2
- FRZB | c.479-2A>T p.X160_splice | Splice Site (SNP) | VAF 7/93 reads (8%) | catalogued as COSV54554602; called by muse, mutect2
- GDF5 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65501945; called by muse, mutect2
- GFPT1 | c.1510G>T p.V504L (on ENST00000357308 / NM_001244710.2; = p.V486L on NM_002056.4) | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV61948621; called by muse, mutect2, varscan2
- GLP2R | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52326159; called by muse, mutect2, varscan2
- GRID2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56220748; called by muse, mutect2
- GRK5 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV64866728; called by muse, mutect2
- GYS2 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV53924634; called by muse, mutect2
- HBD | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV53082946, COSV53083332; called by muse, mutect2
- HCST | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/556 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52887938; called by muse, mutect2
- IGHV3-20 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782671152; called by muse, mutect2
- IL9R | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753927767, COSV99729579; called by muse, mutect2, varscan2
- IMMT | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480837; called by muse, mutect2
- ITGA11 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59878749; called by muse, mutect2
- ITGAX | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV51647027, COSV51651894; called by muse, mutect2, varscan2
- KCNK9 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV57283067; called by muse, mutect2, varscan2
- KCNT2 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54086765, COSV54100416; called by muse, mutect2, varscan2
- KMT2D | c.5837G>C p.G1946A | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56453057; called by muse, mutect2
- KPNB1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51597852; called by muse, mutect2
- LCE3E | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV64231901; called by muse, mutect2
- LRRC15 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV61649919; called by muse, mutect2, varscan2
- LYPLAL1 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as COSV65106842; called by muse, mutect2
- MARK1 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65068372; called by muse, mutect2
- MGAT4A | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53847952; called by muse, mutect2
- MMD | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV50435153; called by muse, mutect2
- MMP16 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54171236; called by muse, mutect2, varscan2
- MMP20 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV52776296; called by muse, mutect2
- MUC16 | c.31696G>C p.E10566Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as COSV67474289; called by muse, mutect2
- MUC5AC | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.25); catalogued as COSV62254324; called by muse, mutect2
- MUC5B | c.12962C>A p.T4321N | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.267); catalogued as COSV71593115; called by muse, mutect2
- MYH13 | c.3732G>C p.K1244N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52832420; called by muse, mutect2
- MYH2 | c.4684G>T p.G1562* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | catalogued as COSV55440845; called by muse, mutect2
- MYO1C | c.586A>T p.S196C (on ENST00000648651 / NM_001080779.2; = p.S161C on NM_033375.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62999542; called by muse, mutect2
- NELL2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61577497; called by muse, mutect2, varscan2
- NOL6 | c.1779G>T p.Q593H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53042866; called by muse, mutect2, varscan2
- NPAP1 | c.2910T>G p.S970R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV61508148; called by muse, mutect2
- NRXN1 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100454322; called by muse, mutect2
- NSRP1 | c.897T>G p.S299R | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55934240; called by muse, mutect2
- NUDCD1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53457805; called by muse, mutect2
- OMD | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65020284; called by muse, mutect2, varscan2
- OR11H4 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59560447; called by muse, mutect2, varscan2
- OR2M5 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV63546498; called by muse, mutect2, varscan2
- OR2T34 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV60899605, COSV60900803; called by muse, mutect2
- OR2T6 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV63216560; called by muse, mutect2
- OR4P4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV58922531; called by muse, mutect2, varscan2
- OR51D1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62914311, COSV62914347; called by muse, mutect2, varscan2
- OR5M3 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs973923348, COSV56567255; called by muse, mutect2
- OR6F1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57468272, COSV57469037; called by muse, mutect2, varscan2
- OR8B8 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60144900; called by muse, mutect2
- OVCH1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs745853862, COSV58964568; called by muse, varscan2
- PACSIN3 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066424; called by muse, mutect2
- PASD1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV64854226, COSV64855802; called by muse, mutect2, varscan2
- PASD1 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV64855806; called by muse, mutect2, varscan2
- PAX2 | c.998T>A p.M333K (on ENST00000428433 / NM_003987.5; = p.M310K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV62291582; called by muse, mutect2
- PAX4 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58387547, COSV58389431; called by muse, mutect2, varscan2
- PCDH11X | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.927); catalogued as COSV53476362; called by mutect2, varscan2
- PCDHB7 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); catalogued as COSV50772567, COSV50778733; called by muse, mutect2
- PCNX2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50814344; called by muse, mutect2
- PDGFRA | c.3096G>T p.E1032D | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57269695; called by muse, mutect2
- PDSS2 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV64655629; called by muse, mutect2, varscan2
- PEG3 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV55637266; called by muse, mutect2, varscan2
- PEX12 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56778315; called by muse, mutect2, varscan2
- PID1 | c.144G>T p.M48I (on ENST00000354069 / NM_001330156.1; = p.M46I on NM_017933.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV62477267; called by muse, mutect2, varscan2
- PKHD1 | c.6972C>G p.I2324M | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61881760; called by muse, mutect2
- PLEKHH2 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV56756212; called by muse, mutect2, varscan2
- POLR2B | c.3346G>T p.V1116F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV55274114, COSV55274330; called by muse, mutect2, varscan2
- PPP1R7 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV52145477; called by muse, mutect2
- PRKG2 | c.462-2A>T p.X154_splice | Splice Site (SNP) | VAF 8/130 reads (6%) | catalogued as COSV52326354; called by muse, mutect2
- PTK2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV61787476; called by muse, mutect2
- PTPN9 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60724282; called by muse, mutect2
- PTPRD | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61956710; called by muse, mutect2, varscan2
- RAB11FIP1 | c.372-2A>C p.X124_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as COSV54761114; called by muse, mutect2
- RALGPS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52224631; called by muse, mutect2
- RALYL | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV72822111, COSV72822148; called by mutect2, varscan2
- REST | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58361264, COSV58361801; called by muse, mutect2
- RUFY2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV61191497; called by mutect2, varscan2
- RYR3 | c.14436A>T p.L4812F (on ENST00000389232; = p.L4813F on NM_001036.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV66784648, COSV66795340; called by muse, mutect2, varscan2
- SBK1 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59397453; called by muse, mutect2, varscan2
- SEMA6D | c.2255G>A p.G752E (on ENST00000316364 / NM_153618.2; = p.G690E on NM_020858.2) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV60379103; called by muse, mutect2
- SLC12A2 | c.3154T>A p.C1052S | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52472668; called by muse, mutect2, varscan2
- SLC6A19 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs375879452, COSV58672096, COSV58675414; called by muse, mutect2
- SLC6A5 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54228152; called by muse, mutect2, varscan2
- SLC7A7 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV53537439; called by muse, mutect2, varscan2
- SPANXN3 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV65140477; called by muse, mutect2, varscan2
- SPIRE1 | c.1356G>C p.K452N (on ENST00000409402 / NM_001128626.2; = p.K438N on NM_020148.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.234); catalogued as COSV59157949; called by muse, mutect2, varscan2
- SSX3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53644495; called by muse, mutect2, varscan2
- STARD10 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV58325889; called by muse, mutect2
- STON1-GTF2A1L | c.3176C>T p.T1059I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59132255; called by muse, mutect2
- TAF1L | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774366817, COSV54261717; called by muse, mutect2, varscan2
- TBC1D1 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 12/191 reads (6%) | catalogued as COSV99790924; called by muse, mutect2
- TDRD5 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54242966; called by muse, mutect2
- TMEM132B | c.3073A>T p.K1025* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV54757343; called by muse, mutect2
- TMPRSS3 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52304286; called by muse, mutect2
- TPX2 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778633428, COSV55920304; called by muse, mutect2, varscan2
- TRIM29 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs767499147, COSV59280375, COSV59280957; called by muse, mutect2, varscan2
- TUBA8 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV57813279; called by muse, mutect2, varscan2
- UGT2B7 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV59443915; called by muse, mutect2
- USH2A | c.7657T>A p.W2553R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56386959; called by muse, mutect2
- USH2A | c.5399G>C p.W1800S | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149920, COSV56386971; called by muse, varscan2
- USP32 | c.4753G>T p.D1585Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56270778; called by mutect2, varscan2
- USP9X | c.5015G>T p.R1672M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61070852; called by muse, mutect2, varscan2
- VIRMA | c.4792A>G p.T1598A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52586517; called by muse, mutect2
- WDPCP | c.2191-1G>T p.X731_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99704738; called by muse, mutect2, varscan2
- WIPI1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50930357; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54297140; called by muse, mutect2, varscan2
- ZC3HAV1 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV54297154; called by muse, mutect2
- ZFPM2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV65874291; called by muse, mutect2
- ZNF479 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58639805; called by muse, mutect2
- ATR | c.6898-3del | Splice Region (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.3364G>T p.G1122W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- HEATR9 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABCG1 | c.894G>T p.R298= | Silent (SNP) | VAF 20/359 reads (6%) | catalogued as COSV59206032; called by muse, mutect2
- ADGRG4 | c.6919C>A p.R2307= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs376547734, COSV54959019; called by muse, mutect2, varscan2
- ANO6 | c.1290G>A p.V430= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs1308184708, COSV57662771; called by muse, mutect2, varscan2
- APMAP | c.180G>T p.L60= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV54174675; called by muse, mutect2
- ARHGAP25 | c.507A>G p.E169= (on ENST00000409202 / NM_001007231.3; = p.E161= on NM_014882.3) | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV54903808; called by muse, mutect2
- ATP8B2 | c.3243C>T p.P1081= (on ENST00000672630; = p.P1048= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/225 reads (12%) | catalogued as COSV59246625; called by muse, mutect2, varscan2
- C1orf226 | c.444G>A p.L148= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV63395721; called by muse, mutect2
- CASP4 | c.198T>C p.R66= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs1260480052, COSV67744533; called by muse, mutect2
- CD1E | c.693T>C p.H231= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs1226448121, COSV63771412; called by muse, mutect2, varscan2
- CDH20 | c.279C>A p.S93= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53006176, COSV53011939; called by muse, mutect2, varscan2
- CELSR2 | c.6909G>A p.T2303= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs150014940; called by muse, mutect2
- CGNL1 | c.1047A>G p.S349= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1360349045, COSV55569983; called by muse, mutect2, varscan2
- CNTNAP2 | c.492G>T p.L164= | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as COSV62201645; called by muse, mutect2
- CTSC | c.1092G>A p.L364= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV57058536; called by muse, mutect2, varscan2
- CYYR1 | c.30A>T p.P10= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as COSV54833623; called by muse, mutect2
- DNAI2 | c.969G>A p.L323= | Silent (SNP) | VAF 34/228 reads (15%) | catalogued as COSV56759550; called by muse, mutect2, varscan2
- DPEP2 | c.1431C>A p.A477= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as COSV52054913; called by muse, mutect2, varscan2
- ERO1B | c.1231C>T p.L411= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV51596079; called by muse, mutect2, varscan2
- FAM107A | c.102G>T p.L34= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV62980782; called by muse, mutect2, varscan2
- FMN2 | c.2388C>A p.V796= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV60435299; called by muse, mutect2, varscan2
- FOXP2 | c.993G>T p.S331= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100646128, COSV63488109; called by mutect2, varscan2
- GFRA3 | c.684G>T p.G228= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV51229096, COSV99218344; called by muse, mutect2, varscan2
- GLI2 | c.759C>G p.P253= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV58044478; called by muse, mutect2
- GPR61 | c.867C>A p.L289= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV63983960; called by muse, mutect2
- GPRASP2 | c.2355G>A p.Q785= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV59991699; called by muse, mutect2
- H2BW1 | c.468C>T p.S156= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs370071971, COSV54220528; called by muse, mutect2, varscan2
- HOXA5 | c.480G>A p.A160= | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as rs202017218, COSV56073789; called by muse, mutect2
- HYDIN | c.14979C>A p.P4993= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV66639727; called by muse, mutect2, varscan2
- IL7R | c.1248C>G p.P416= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100286448, COSV57409599; called by muse, mutect2, varscan2
- IL9R | c.441G>C p.L147= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99729573; called by muse, mutect2, varscan2
- ITGAD | c.2595C>A p.P865= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV66758486; called by muse, mutect2
- MS4A6E | c.30C>G p.T10= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV55727249; called by muse, mutect2
- MUC16 | c.11475A>C p.P3825= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV101202441, COSV67474302; called by muse, mutect2
- MYOM3 | c.303G>A p.R101= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1201152247, COSV58395469; called by muse, mutect2
- NALCN | c.2109C>T p.I703= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as rs1019776644, COSV51943405; called by muse, mutect2, varscan2
- NIBAN3 | c.1959T>C p.S653= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV53109837; called by muse, mutect2
- NLRP2 | c.2955C>T p.V985= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV54756469; called by muse, mutect2
- OR10X1 | c.903C>T p.I301= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV63767237, COSV63767322; called by muse, mutect2, varscan2
- OR6V1 | c.168C>G p.P56= | Silent (SNP) | VAF 18/292 reads (6%) | catalogued as COSV69237394; called by muse, mutect2
- OSBPL10 | c.675A>T p.A225= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV67340627; called by muse, mutect2, varscan2
- P2RY8 | c.312C>T p.Y104= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1425189992, COSV67176956; called by muse, mutect2
- PDE6H | c.243G>A p.G81= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV56760841; called by muse, mutect2, varscan2
- PKHD1L1 | c.2997A>G p.L999= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV65737613, COSV65745656; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>T p.G2768= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PTPRC | c.408C>T p.L136= | Silent (SNP) | VAF 14/364 reads (4%) | catalogued as rs1239293392, COSV61414078; called by muse, mutect2
- PTPRZ1 | c.288T>C p.H96= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV66439364; called by muse, mutect2
- SALL2 | c.972C>T p.T324= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1181391004, COSV58103963; called by muse, varscan2
- SCD5 | c.351C>T p.S117= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs936938166, COSV51103065; called by muse, mutect2
- SERTAD2 | c.258C>T p.F86= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1261100399, COSV57640538; called by mutect2, varscan2
- SLAIN2 | c.846C>G p.A282= | Silent (SNP) | VAF 16/224 reads (7%) | catalogued as COSV51907521; called by muse, mutect2
- SLC5A1 | c.1077T>A p.V359= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV56686288; called by muse, mutect2
- SLC6A15 | c.549T>A p.P183= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV57022416, COSV57025231; called by muse, mutect2, varscan2
- TFDP3 | c.1149A>G p.P383= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV59537450; called by muse, mutect2
- WDR89 | c.813A>G p.E271= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV50827001; called by muse, mutect2, varscan2
- ZNF536 | c.2151C>A p.P717= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV62826482; called by muse, mutect2, varscan2
- ZNF682 | c.684A>C p.P228= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1215931064, COSV62066272; called by muse, mutect2
- AL353804.4 | chrX:73822244 G>T | 5'Flank (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472260 G>T | 3'Flank (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
